Surgical pathology report (de-identified scan), TCGA case TCGA-G7-6793, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-6793-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. KIDNEY LEFT
- B. LYMPH NODES INTER-AORTIC CAVAL
- C. LYMPH NODES PERI-AORTIC

SPECIMEN(S):

- A. KIDNEY LEFT
- B. LYMPH NODES INTER-AORTIC CAVAL
- C. LYMPH NODES PERI-AORTIC

GROSS DESCRIPTION:

A. KIDNEY LEFT

Received fresh is a 1,098 gram nephrectomy specimen with attached perinephric fat measuring 23 x 14 x 9 cm. The cortical surface has a nodular appearance. The kidney proper is 18 x 12 x 8 cm. The parenchyma has been replaced by a papillary tan-brown mass measuring 17 x 11.8 x 8 cm. It has obliterated the renal pelvis and calyces. Areas of hemorrhage and necrosis are noted. There are clear fluid filled cysts throughout. There is a rim of normal appearing renal tissue measuring 4.5 x 3.5 x 2.1 cm. On sectioning through the mass it extends into the perinephric fat. In the hilar region there is a nodule that measures 6.3 x 4.7 x 2.7 cm. On sectioning, it appears to be an extension of a tubular structure. No adrenal gland is identified and within the perinephric fat lymph nodes are found ranging in size from 0.1 to 0.3 cm. Representative sections were taken for tissue procurement and a gross photograph was taken. Representative sections are submitted in A1 (vascular and ureteral margins), A2-A12 (tumor), A13 (renal parenchyma), and A14-A17 (multiple possible lymph nodes).

B. LYMPH NODES INTER-AORTIC CAVAL

Received in formalin is a piece of yellow-tan adipose tissue measuring 3.7 x 2.2 x 0.8 cm. Eight possible lymph nodes are identified ranging in size from 0.1 to 0.8 cm. Specimen is submitted in B1 (lymph nodes), B2-B4 (one lymph node), B5 (the rest of tissue).

C. LYMPH NODES PERI-AORTIC

Received in formalin is a piece of yellow-tan adipose tissue measuring 3.5 x 3.2 x 1.2 cm. Three lymph nodes are identified ranging from 0.6 to 4.7 cm. in greatest dimension. Specimen is submitted in C1 (one lymph node), C2-C3 (one lymph node), C4-C5 (one lymph node), and C6 (the rest of tissue).

DIAGNOSIS:

A. KIDNEY, LEFT, RADICAL NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA, TYPE 2, INVADING PERIRENAL AND RENAL SINUS ADIPOSE TISSUE
- TUMOR SIZE 17 X 11.8 X 8 CM
- FUHRMAN NUCLEAR GRADE 3
- METASTATIC CARCINOMA TO SEVEN OUT OF SEVEN LYMPH PERINEPHRIC LYMPH NODES (7/7)
- VASCULAR AND URETERAL MARGINS NEGATIVE FOR CARCINOMA (SEE NOTE)
- SEE SYNOPSIS REPORT

B. LYMPH NODES, INTER-AORTIC CAVAL, EXCISION:

- NO TUMOR SEEN IN FOUR LYMPH NODES (0/4)

C. LYMPH NODES, PERI-AORTIC, EXCISION:

- METASTATIC CARCINOMA TO TWO OUT OF FOUR LYMPH NODES (2/4)

NOTE: There are numerous perinephric-adipose-tissue tumor depositions/lymph node involvements. The tumor is present at the inked surface in one of these foci; therefore correlation with the surgical findings is recommended for better assessment of the final status of the Gerota's fascial margin.

SYNOPSIS REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimen Type: Radical nephrectomy

Without adrenal gland

Laterality: Left

Tumor Site: Upper pole

Middle pole

Lower pole

Focality: Unifocal

[page 2 of 2]
Tumor Size (largest tumor if multiple): Greatest dimension: 17cm
Additional dimensions: 11.8cm x 8cm
Macroscopic Extent of Tumor: Tumor extension into perinephric tissues
WHO CLASSIFICATION
Papillary renal cell carcinoma 8260/3
Comment(s): Type 2
Histologic Grade (Fuhrman Nuclear Grade):
G3: Nuclei very irregular, approximately 20 u; nucleoli large and prominent
Invasion of Vascular/Lymphatic: Present
Perinephric Tissue Invasion: Absent
Margins: Margins uninvolved by invasive carcinoma
Adrenal Gland: Not present
Regional Lymph Nodes: Positive 9 / 15
Additional Findings: None identified
Pathological Staging (pTNM): pT 3a N 2 M x

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

Source: NCI Genomic Data Commons file e2144468-edce-4ac5-9c86-81df6361a95d (TCGA-G7-6793.F6A5B56D-2A3C-4296-A72D-A76023797AD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).